Somatic mutation profile of tumor specimen ALCH-AEBR-TTP1-A (aliquot ALCH-AEBR-TTP1-A-2-0-D-A657-36) from ALCHEMIST case ALCH-AEBR, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.0 years (23,734 days).
Specimen ALCH-AEBR-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7b80c1c-ef5d-47bd-b9fd-e337ab450b14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEBR-NB1-A (Blood Derived Normal), aliquot ALCH-AEBR-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/16e15f6b-5b6f-4e08-91b8-24d71b816a26

The open-access MAF lists 93 somatic variants for this specimen: 67 protein-altering or splice-affecting, 19 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 58, Silent 19, Frame Shift Del 4, 3'UTR 3, Intron 3, Nonsense Mutation 2, Splice Site 1, Splice Region 1, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASH1L | c.5506C>T p.Q1836* | Nonsense Mutation (SNP) | VAF 28/242 reads (12%) | catalogued as rs1558105796; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 48/430 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 46/430 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- TP53 | c.577C>T p.H193Y | Missense Mutation (SNP) | VAF 29/250 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876658468, COSV52675896, COSV52688299, COSV52757395; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C1orf112 | c.1457C>T p.S486L | Missense Mutation (SNP) | VAF 43/250 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.069); catalogued as rs997421354; called by muse, mutect2, varscan2
- DBX2 | c.555G>T p.R185S | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60337101; called by muse, mutect2
- EGFLAM | c.679C>A p.R227S | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.217); catalogued as rs149843559; called by mutect2, varscan2
- FAM135B | c.1793del p.G598Vfs*18 | Frame Shift Del (DEL) | VAF 18/181 reads (10%) | catalogued as COSV99417748; called by mutect2, varscan2
- HAS2 | c.223del p.L75* | Frame Shift Del (DEL) | VAF 49/496 reads (10%) | catalogued as rs768013252; called by pindel, varscan2
- KIAA2026 | c.3621G>T p.E1207D | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV67355652; called by muse, mutect2
- LRIG2 | c.2916del p.T973Pfs*6 | Frame Shift Del (DEL) | VAF 18/206 reads (9%) | catalogued as COSV100743699; called by mutect2, pindel
- MROH5 | c.266C>A p.T89N | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as rs1023929848; called by muse, mutect2, varscan2
- NOP53 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.145); catalogued as rs1223467869; called by muse, mutect2
- OR8K3 | c.364C>A p.L122I | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as COSV57131294, COSV57132205; called by muse, mutect2
- RIMS1 | c.1060A>G p.R354G | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1486994536; called by muse, mutect2
- RIMS1 | c.2809A>G p.T937A | Missense Mutation (SNP) | VAF 14/322 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99324158; called by muse, mutect2
- SATB2 | c.1504C>A p.Q502K | Missense Mutation (SNP) | VAF 30/605 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53477260; called by muse, mutect2
- SOAT2 | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as rs4244355; called by muse, mutect2, varscan2
- THEMIS | c.446T>C p.M149T | Missense Mutation (SNP) | VAF 38/438 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs759891900, COSV64072282; called by muse, mutect2
- TMEM106B | c.380G>T p.G127V | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67544109; called by muse, mutect2
- TRIM42 | c.688G>C p.D230H | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53886835; called by muse, mutect2
- XDH | c.2168G>T p.G723V | Missense Mutation (SNP) | VAF 32/608 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV65148858, COSV65149548; called by muse, mutect2
- ZNF90 | c.659A>G p.K220R | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.649); catalogued as rs1555705963; called by muse, mutect2, varscan2
- ACTR2 | c.393C>A p.Y131* | Nonsense Mutation (SNP) | VAF 13/235 reads (6%) | called by muse, mutect2
- ARL5B | c.94A>T p.I32F | Missense Mutation (SNP) | VAF 25/173 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- ATP1B1 | c.836A>T p.Y279F | Missense Mutation (SNP) | VAF 49/375 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- CDC14A | c.686A>G p.K229R | Missense Mutation (SNP) | VAF 48/534 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.53); called by muse, mutect2
- CFAP77 | c.92C>A p.P31H | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CMTR2 | c.706G>T p.G236W | Missense Mutation (SNP) | VAF 24/199 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKI | c.672G>T p.Q224H | Missense Mutation (SNP) | VAF 21/229 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); called by muse, mutect2
- DRAM1 | c.190G>T p.A64S | Missense Mutation (SNP) | VAF 17/311 reads (5%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); called by muse, mutect2
- EDIL3 | c.463C>A p.Q155K | Missense Mutation (SNP) | VAF 15/188 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.093); called by muse, mutect2
- EFCAB13 | c.2519C>T p.T840I | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- EPHA6 | c.2289C>A p.H763Q (on ENST00000389672 / NM_001080448.3; = p.H155Q on NM_173655.4) | Missense Mutation (SNP) | VAF 12/276 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.417); called by muse, mutect2
- FOLH1B | n.901+1G>T | Splice Site (SNP) | VAF 16/166 reads (10%) | called by muse, mutect2
- FSD2 | c.191A>G p.Q64R | Missense Mutation (SNP) | VAF 11/148 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- FSTL5 | c.1499G>T p.R500M | Missense Mutation (SNP) | VAF 21/260 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.186); called by muse, mutect2
- GADD45B | c.242_244del p.F81del | In Frame Del (DEL) | VAF 7/76 reads (9%) | called by mutect2, pindel
- HP | c.526C>A p.Q176K | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IGF2 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- IL18RAP | c.1422C>A p.S474R | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNA4 | c.1700A>G p.Y567C | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- KLHL7 | c.691G>T p.A231S (on ENST00000339077 / NM_001031710.3; = p.A183S on NM_018846.5) | Missense Mutation (SNP) | VAF 40/576 reads (7%) | SIFT tolerated (0.7); PolyPhen benign (0.007); called by muse, mutect2
- LYST | c.11266A>T p.S3756C | Missense Mutation (SNP) | VAF 12/393 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- MTDH | c.284_294del p.V95Gfs*36 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- NXPE4 | c.1519A>T p.S507C (on ENST00000375478 / NM_001077639.2; = p.S223C on NM_017678.3) | Missense Mutation (SNP) | VAF 11/314 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2
- OR8K3 | c.71A>T p.Q24L | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); called by muse, mutect2
- POM121L2 | c.689A>G p.K230R | Missense Mutation (SNP) | VAF 17/225 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.145); called by muse, mutect2
- PRKDC | c.376C>G p.P126A | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.014); called by muse, mutect2
- RAD21L1 | c.1219G>C p.E407Q | Missense Mutation (SNP) | VAF 13/336 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2
- SCRT2 | c.527C>A p.T176K | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SDK2 | c.3010A>T p.I1004F | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SIGMAR1 | c.614C>G p.S205C | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); called by muse, mutect2
- SKOR2 | c.2908C>A p.P970T | Missense Mutation (SNP) | VAF 14/130 reads (11%) | SIFT deleterious, low confidence (0.02); called by muse, mutect2
- SMAD4 | c.905G>T p.W302L | Missense Mutation (SNP) | VAF 23/453 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.097); called by muse, mutect2
- SPOCK1 | c.1048G>C p.G350R | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2
- SPTBN5 | c.3609G>C p.W1203C | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2
- TAAR6 | c.869C>A p.A290D | Missense Mutation (SNP) | VAF 20/253 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- TENM1 | c.6463G>T p.A2155S | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- THOC1 | c.448T>A p.S150T | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.619); called by muse, mutect2
- TIGD1 | c.967A>T p.M323L | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMPRSS15 | c.60G>C p.M20I | Missense Mutation (SNP) | VAF 26/600 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0.013); called by muse, mutect2
- TMX3 | c.735A>G p.T245= | Splice Region (SNP) | VAF 32/342 reads (9%) | called by muse, mutect2
- TRRAP | c.2945A>C p.H982P | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- XIRP2 | c.517G>T p.V173F (on ENST00000628543; = p.V348F on NM_152381.6) | Missense Mutation (SNP) | VAF 36/314 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- ZNF578 | c.794G>A p.G265D | Missense Mutation (SNP) | VAF 21/242 reads (9%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZSCAN5A | c.115G>T p.D39Y | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- ADGRG2 | c.1170G>A p.L390= (on ENST00000379869 / NM_001079858.3; = p.L387= on NM_005756.4) | Silent (SNP) | VAF 7/113 reads (6%) | called by muse, mutect2
- AKR1B1 | c.114C>T p.V38= | Silent (SNP) | VAF 31/258 reads (12%) | catalogued as rs779124069, COSV53648937; called by muse, mutect2, varscan2
- ALDOA | c.507C>T p.P169= (on ENST00000642816 / NM_001243177.4; = p.P115= on NM_184041.5) | Silent (SNP) | VAF 10/317 reads (3%) | catalogued as COSV100582048; called by muse, mutect2
- ATP6V1C1 | c.610C>T p.L204= | Silent (SNP) | VAF 38/484 reads (8%) | called by muse, mutect2
- CD163L1 | c.1032C>T p.S344= | Silent (SNP) | VAF 29/460 reads (6%) | catalogued as rs1464957571, COSV58019640; called by muse, mutect2
- CFAP54 | c.171C>G p.P57= | Silent (SNP) | VAF 24/251 reads (10%) | called by muse, mutect2
- CLEC16A | c.1464G>T p.A488= | Silent (SNP) | VAF 18/199 reads (9%) | catalogued as rs1239707469; called by muse, mutect2
- DIDO1 | c.5061G>A p.G1687= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- DLX6 | c.780G>C p.S260= | Silent (SNP) | VAF 22/254 reads (9%) | catalogued as rs377688666, COSV50292851; called by muse, mutect2
- EIF4A1 | c.219T>A p.I73= | Silent (SNP) | VAF 9/103 reads (9%) | called by muse, mutect2
- LGALS3BP | c.291G>A p.E97= | Silent (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- LSS | c.1050G>T p.V350= | Silent (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- ORC1 | c.1485G>T p.L495= | Silent (SNP) | VAF 34/443 reads (8%) | called by muse, mutect2
- PCDHA5 | c.309C>A p.I103= | Silent (SNP) | VAF 16/253 reads (6%) | catalogued as rs782613574, COSV100972469; called by muse, mutect2
- PDE10A | c.2220C>A p.T740= | Silent (SNP) | VAF 14/266 reads (5%) | catalogued as COSV63100654; called by muse, mutect2
- SAMD9 | c.2388C>A p.L796= | Silent (SNP) | VAF 83/570 reads (15%) | catalogued as rs760624546, COSV66072688; called by muse, mutect2, varscan2
- SLC44A3 | c.1470C>T p.L490= (on ENST00000271227 / NM_001114106.3; = p.L442= on NM_152369.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- SLITRK4 | c.2259G>A p.R753= | Silent (SNP) | VAF 19/293 reads (6%) | catalogued as COSV62025380; called by muse, mutect2
- ZNF579 | c.12G>A p.Q4= | Silent (SNP) | VAF 4/22 reads (18%) | called by mutect2, varscan2
- EARS2 | c.*2538C>T | 3'UTR (SNP) | VAF 15/280 reads (5%) | called by muse, mutect2
- GABRB2 | c.1191+9G>C | Intron (SNP) | VAF 7/166 reads (4%) | called by muse, mutect2
- GNG2 | c.87+1149G>T | Intron (SNP) | VAF 24/241 reads (10%) | called by muse, mutect2
- LRRC2 | c.-20+540G>A | Intron (SNP) | VAF 10/217 reads (5%) | called by muse, mutect2
- SZT2 | c.*1898G>A | 3'UTR (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- UQCRB | c.*4360G>T | 3'UTR (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2
- ZNF208 | c.-38C>A | 5'UTR (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
